Gene-level copy-number profile of tumor specimen BLGSP-71-23-00410-01B from CGCI case BLGSP-71-23-00410, project CGCI-BLGSP (Burkitt Lymphoma Genome Sequencing Project). Sex at birth: female; Vital status: Dead; Primary diagnosis: Burkitt lymphoma, NOS (Includes all variants); Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 6.6 years (2,412 days).
Specimen BLGSP-71-23-00410-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file a73f0d4f-0a7f-4d58-94ee-596c403caa3b.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator BLGSP-71-23-00410-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,248 have no estimate.
https://portal.gdc.cancer.gov/files/6358b488-e3bb-42a7-bd48-1ec55737a20f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 53; copy number 1: 460; copy number 2: 56,068; copy number 3: 1,466; copy number 4: 302; copy number 5: 18; copy number 6: 8.

Homozygous deletions (total copy number 0; autosomes only): 53 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:105,851,705–106,122,709, 52 genes (within-gene range 0–3): IGHM, MIR4539, MIR4507, MIR4538, MIR4537, IGHD1-26, IGHD6-25, IGHD5-24, IGHD4-23, IGHD3-22, IGHD2-21, AC246787.2, IGHD1-20, IGHD6-19, IGHD5-18, IGHD4-17, IGHD3-16, IGHD2-15, IGHD1-14, IGHD6-13, IGHD5-12, IGHD4-11, IGHD3-10, IGHD3-9, IGHD2-8, IGHD1-7, IGHD6-6, IGHD5-5, IGHD4-4, IGHD3-3, IGHD2-2, FAM30A, IGHD1-1, IGHV6-1, IGHVII-1-1, ADAM6, AC246787.1, IGHV1-2, IGHVIII-2-1, IGHV1-3, IGHV4-4, IGHV7-4-1, IGHV2-5, IGHVIII-5-1, IGHVIII-5-2, IGHV3-6, IGHV3-7, IGHV3-64D, IGHV5-10-1, IGHV3-11, IGHVIII-11-1, IGHV1-12.
- chr14:106,170,749–106,171,052, 1 gene (within-gene range 0–2): IGHVIII-16-1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 26 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:89,252,211–89,297,785, 7 genes, copy number 6: IGKV3-31, IGKV1-32, IGKV1-33, IGKV3-34, IGKV1-35, IGKV2-36, IGKV1-37.
- chr2:136,114,349–136,118,149, 1 gene, copy number 6: CXCR4.
- chr13:46,374,401–46,410,557, 2 genes, copy number 5: RNU2-6P, RNU6-68P.
- chr14:95,709,947–95,757,656, 2 genes, copy number 5: TCL1A, AL139020.1.
- chr22:22,822,658–22,823,289, 2 genes, copy number 5 (within-gene range 4–5): IGLV2-8, MIR650.
- chr22:22,899,481–22,923,034, 12 genes, copy number 5: IGLJ2, IGLC2, IGLJ3, IGLC3, IGLJ4, IGLC4, IGLJ5, IGLC5, IGLJ6, IGLC6, IGLJ7, IGLC7.

Autosomal genes at a single copy (total copy number 1): 458. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
